Surgical pathology report (de-identified scan), TCGA case TCGA-MU-A8JM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Minnesota, specimen TCGA-MU-A8JM-01A (Primary Tumor).

[page 1 of 9]
ICD-O-3

Carcinoma, squamous cell non-keratinizing NOS
8072/3

Site: Cervix NOS
C53.9

gjs 1/27/14

Date of Tumor Procurement:

SPECIMEN(S):

A: Right pelvic lymph node

B: Right common lymph node

C: Left external iliac lymph nodes

D: Left obturator lymph node

E: Uterus, cervix, bilateral fallopian tubes and ovaries with bilateral
parametira and upper vagina

FINAL DIAGNOSIS:

A. Right pelvic lymph node, excision:

- Eleven lymph nodes negative for metastatic carcinoma (0/11)

B. Right common lymph node, excision:

- Four lymph nodes negative for metastatic carcinoma (0/4)

C. Left external iliac lymph node, excision:

- Six lymph nodes negative for metastatic carcinoma (0/6)

D. Left obturator lymph node, excision:

- Four lymph nodes negative for metastatic carcinoma (0/4)

[page 2 of 9]
E. Uterus, cervix, bilateral ovaries and fallopian tubes, bilateral parametria and upper vagina; radical hysterectomy with bilateral salpingo-oophorectomy:

- Squamous cell carcinoma of the cervix characterized by:
- Size: 2.3 cm (greatest dimension)
- Histologic grade: Moderately differentiated (G2)
- Stromal invasion: 1.1 cm
- Angiolymphatic invasion: Absent
- Margins: Negative, 0.7 cm from closest (parametrial) margin
- Background cervix showing high grade intraepithelial neoplasia

- Four parametrial lymph nodes negative for metastatic carcinoma

(0/4)

- Uterus, right and left fallopian tubes and ovaries negative for carcinoma

- Additional findings:
- Benign leiomyomas of the uterus
- Benign paratubal cysts
- Benign ovarian inclusion cysts with hemorrhage
- See staging parameters below

COMMENT:

Specimen: Cervix, uterine corpus, bilateral ovaries and bilateral fallopian tubes

[page 3 of 9]
Procedure: Radical hysterectomy

Tumor Size

Greatest dimension: 2.3cm

Additional dimensions: 2.0 x 1.5 cm

Tumor Site: Left inferior quadrant (3 to 6 o'clock), right inferior quadrant (6 to 9 o'clock) and right superior quadrant (9 to 12 o'clock)

Histologic Type: Squamous cell carcinoma, nonkeratinizing

Histologic Grade: G2, Moderately differentiated

Margins: Uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest parametrium margin: 7 mm

Carcinoma in situ not identified at distal margin

Lymph-Vascular Invasion: Not identified

Number of Lymph Nodes Examined: 29

Number of Lymph Nodes Involved: 0

Additional Pathologic Findings: Intraepithelial neoplasia (specifies type and grade): CIN II, CIN III/CIS

Distant Metastasis (pM): Not applicable

Pathologic Staging (pTNM [FIGO]): pT1b1 NO Mx

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

[page 4 of 9]
The patient is a -year-old female with cervix cancer. Operative

Procedure: Total hysterectomy with bilateral salpingo-oophorectomy,
upper vagina resection and pelvic lymph node dissection.

GROSS:

Five containers are received, each labeled with the patient's name, and medical record number.

A. The first container is received fresh for intraoperative consultation and labeled "A-right pelvic lymph node." The specimen consists of a 4.5 x 4.0 x 3.0 cm portion of yellow lobulated fibroadipose tissue. Sectioning reveals six lymph nodes ranging from 0.4 to 2.0 cm in greatest dimension. All these lymph nodes are submitted for frozen sections as remnants.

Summary of Sections:

A1FS - one lymph node.

A1FS - four lymph nodes.

A3FS - one lymph node.

A4-A6 - remaining adipose tissue.

B. The second container is received fresh for intraoperative consultation and labeled "B-right common lymph node." The specimen consists of a 4.5 x 1.8 x 1.0 cm aggregate of yellow lobulated soft adipose tissue. Sectioning reveals two lymph nodes measuring 0.7 and

[page 5 of 9]
2.3 cm in greatest dimension respectively. Both lymph nodes are entirely submitted for frozen section as remnants and are entirely submitted.

Summary of Sections:

B1FS - one lymph node.

B2FS - one lymph node.

B3 - remaining adipose tissue.

C. The next container is received fresh for intraoperative consultation and labeled "C-left external iliac lymph node." The specimen consists of a 4.5 x 4.0 x 2.0 cm aggregate of yellow lobulated adipose tissue. Six lymph nodes ranging from 0.4 to 2.0 cm in greatest dimension are present. Two of six lymph nodes are submitted for frozen section per surgeon request. Representative sections to include all lymph nodes are submitted for permanent.

Summary of Sections:

C1FS - one lymph node.

C2FS - one lymph node.

C3-C6 - one lymph node in each.

D. The next container is also received fresh for intraoperative consultation and labeled "D-left obturator lymph node." The specimen consists of a 3.0 x 1.5 x 0.8 cm aggregate of yellow lobulated adipose

[page 6 of 9]
tissue. Sectioning reveals two lymph nodes measuring 0.5 and 2.0 cm in greatest dimension respectively. Both lymph nodes are entirely submitted for frozen section and the remaining tissue is entirely submitted.

Summary of Sections:

D1FS - one lymph node.

D2FS - one lymph node.

D3 - remaining adipose tissue.

E. The next container is received fresh and subsequently saved in formalin in the container labeled "E-uterus, cervix, bilateral fallopian tubes and ovaries with bilateral parametria and upper vagina." The specimen consists of a 102 gm 8.5 x 5.8 x 3.8 cm total hysterectomy specimen with attached bilateral fallopian tubes and ovaries. A 6.0 cm in greatest circumference by 2.0 cm in greatest length vaginal cuff is attached on the cervix. A moderate amount of parametrium is attached on the cervix. The entire parametrial margin is inked black. The serosa is tan-white and smooth with a 0.4 x 0.3 x 0.2 cm white firm subserosal nodule on the fundus. The ectocervix is tan-white and mostly smooth. The os is widely opened. The uterus is bisected to reveal a 2.3 x 2.0 cm red, ill-defined, firm, ulcerated mass is present in the endocervix and extending both to the os and middle portion of endocervical canal. On sectioning, this ulcerated mass is involved in 3 - 1 o'clock. On sectioning this mass invades up to 1.5 cm to the deep stoma and 0.7 cm

[page 7 of 9]
to the closest parametrial margin. This mass is 1.5 cm to the closest 1 o'clock vaginal margin. The lower uterine segment is grossly not involved. The entire endometrium is red shaggy and measuring up to 0.2 cm in thickness. No polyps or masses are identified. The myometrium is trabeculated and measuring 2.0 cm in thickness. The right and left ovaries are 2.8 x 2.0 x 1.3 cm and 2.5 x 2.2 x 1.0 cm respectively. Sectioning of right ovary reveals a 0.6 cm in greatest dimension cyst filled with serous and clear fluid. Also, a 0.7 cm in greatest dimension hemorrhagic nodule is present on the surface. Sectioning of left ovary reveals a 0.8 x 0.6 x 0.5 cm dark red hemorrhagic small cyst on the surface, which is filled with bright blood clot. No other lesions or masses are identified on both ovaries. The right and left fallopian tube are 6.5 cm in length x 0.7 cm in diameter and 6.0 cm in length x 0.6 cm in diameter respectively. The negation defects are noted on both fallopian tubes. The serosa of both fallopian tubes are mostly smooth with multiple small tubule cysts ranging from less than 0.1 to 0.3 cm in greatest dimension. Sectioning of both fallopian tubes reveals pinpoint lumen and unremarkable mucosa. The fimbria are noted on both fallopian tubes. Representative sections are submitted.

Summary of Sections:

E1-E3 - right parametrial margin, perpendicular.

E4-E6 - left parametrial margin, perpendicular.

E7 - anterior vaginal cuff margin, en face.

E8 - posterior vaginal cuff margin, en face.

[page 8 of 9]
E9-E10 - one full thickness of cervix from 9 o'clock to include a mass with deepest invasion and related parametrial margins.

E11-E12 - one full thickness from 10 o'clock of the cervix to include the mass with deepest invasion and related parametrial margin.

E13 - one full thickness of cervix from 6 o'clock.

E14 - one full thickness of cervix from 12 o'clock.

E15 - one full thickness of cervix from 3 o'clock.

E16 - anterior lower uterine segment.

E17 - two full thickness of anterior endomyometrium.

E18 - posterior lower uterine segment.

E19 - two full thickness of posterior endomyometrium.

E20 - subserosal nodule.

E21 - right ovary to include a small cyst and hemorrhagic nodule.

E22 - right fallopian tube to include the entire fimbria.

E23 - left ovary to include the entire hemorrhagic cyst.

E24 - left fallopian tube to include the entire fimbria.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:

AFS1-A3FS: Right pelvic lymph node. "Negative for tumor."

B1FS-B2FS: Right common lymph node. "Negative for tumor."

C1FS-C2FS: Left external iliac lymph node. "Negative for tumor."

D1FS-D2FS: Left obturator lymph node. "Two lymph nodes negative for tumor."

[page 9 of 9]
MICROSCOPIC:

A-D: The final diagnosis for this case is in agreement with the frozen section diagnosis.

Source: NCI Genomic Data Commons file c5a244b3-5af6-448b-a18b-cfbb4ab50b8c (TCGA-MU-A8JM.A70CA320-58BF-4165-BD92-D791A4385247.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).